Gene-level copy-number profile of tumor specimen TCGA-UU-A93S-01A from TCGA case TCGA-UU-A93S, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.7 years (23,278 days).
Specimen TCGA-UU-A93S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.8f2c56aa-6e4e-4b56-90bf-e70cfc9206f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UU-A93S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e5684f3a-f9e4-48e5-afd3-baf97dacfca4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,421; copy number 2: 14,632; copy number 3: 24,511; copy number 4: 9,875; copy number 5: 4,959; copy number 6: 422; copy number 7: 3,192; copy number 8: 273; copy number 9: 42; copy number 10: 246; copy number 11: 22; copy number 12: 8; copy number 16: 122; copy number 20: 13; copy number 23: 3; copy number 24: 26; copy number 53: 34; copy number 83: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UU-A93S-01A-21D-A41E-01): tumor purity 0.61, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,983 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:60,659,631–61,725,423, 8 genes, copy number 7 (within-gene range 3–7): AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7–10 (broad region; genes not listed).
- chr3:172,425,850–172,725,038, 10 genes, copy number 8: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2.
- chr5:33,944,623–34,124,528, 8 genes, copy number 10 (within-gene range 5–10): SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3.
- chr5:59,528,861–59,529,251, 1 gene, copy number 9: NDUFB4P2.
- chr6:26,871,484–30,725,426, 257 genes, copy number 10–16 (within-gene range 2–16) (broad region; genes not listed).
- chr6:48,701,491–55,282,620, 119 genes, copy number 7–23 (within-gene range 3–23) (broad region; genes not listed).
- chr7:70,972–23,014,130, 359 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr7:25,948,657–26,213,607, 5 genes, copy number 12 (within-gene range 5–12): AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3.
- chr7:44,104,345–45,186,302, 39 genes, copy number 8: AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC004938.2, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2, NACAD, TBRG4, SNORA5A, SNORA5C, SNORA5B, RAMP3.
- chr7:88,759,700–89,338,528, 1 gene, copy number 7 (within-gene range 5–7): ZNF804B.
- chr7:89,443,946–90,513,402, 16 genes, copy number 7: AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1.
- chr7:90,469,639–90,597,353, 2 genes, copy number 7: AC002456.2, AC002456.1.
- chr7:103,471,784–103,989,658, 1 gene, copy number 9 (within-gene range 5–9): RELN.
- chr7:104,126,341–106,770,207, 40 genes, copy number 9 (within-gene range 5–9): ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L.
- chr8:35,235,475–40,901,854, 111 genes, copy number 7 (broad region; genes not listed).
- chr8:68,176,768–73,441,526, 82 genes, copy number 7 (broad region; genes not listed).
- chr8:73,511,276–73,511,654, 1 gene, copy number 7: AC018620.1.
- chr8:81,732,448–83,202,431, 13 genes, copy number 7 (within-gene range 4–7): CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1.
- chr9:4,070,906–4,071,884, 1 gene, copy number 7: AL359095.1.
- chr10:1,177,313–1,737,525, 1 gene, copy number 8 (within-gene range 4–8): ADARB2.
- chr10:1,526,637–12,196,144, 180 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr10:50,305,586–50,625,163, 1 gene, copy number 11 (within-gene range 6–11): SGMS1.
- chr10:50,472,814–50,965,220, 15 genes, copy number 11: AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2.
- chr10:51,062,579–51,068,553, 1 gene, copy number 11: AL731537.1.
- chr13:99,429,211–99,564,048, 5 genes, copy number 8 (within-gene range 5–8): AL136961.1, TM9SF2, LINC01232, AL139035.1, LINC00449.
- chr13:105,690,429–105,797,539, 2 genes, copy number 12 (within-gene range 5–12): AL359745.1, LINC00343.
- chr13:108,251,240–108,308,484, 1 gene, copy number 11 (within-gene range 5–11): TNFSF13B.
- chr13:108,301,212–108,301,331, 1 gene, copy number 11: RNA5SP39.
- chr17:36,948,954–37,056,871, 1 gene, copy number 83 (within-gene range 2–83): AATF.
- chr17:36,998,598–37,052,890, 4 genes, copy number 83: AC244093.4, MIR2909, AC244093.3, AC244093.5.
- chr17:37,140,611–37,163,139, 3 genes, copy number 83: AC244093.1, HMGB1P24, AC244093.2.
- chr17:39,603,536–40,195,656, 34 genes, copy number 53: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867.
- chr17:47,522,942–47,649,420, 3 genes, copy number 24 (within-gene range 2–24): NPEPPS, Y_RNA, AC025682.1.
- chr17:53,276,760–56,838,773, 36 genes, copy number 20–24 (within-gene range 2–24): AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG, C17orf67, AC106858.1.
- chr17:58,951,185–59,281,343, 17 genes, copy number 10: Metazoa_SRP, AC100832.2, TRIM37, RN7SL716P, AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A, PRR11, SPDYE22P, AC099850.2, AC099850.3, SMG8, GDPD1, Y_RNA, SNRPGP17.

Autosomal genes at a single copy (total copy number 1): 1,421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
